Somatic mutation profile of tumor specimen CPT008920 (aliquot CPT008920-0002) from CPTAC case 21BR001, project CPTAC-2 (Breast). Tissue or organ of origin: Breast, NOS.
Specimen CPT008920: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3532de06-865f-4d52-9e7e-f28b4010f23e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT008518 (Blood Derived Normal), aliquot CPT008518-0001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/579b3813-41d5-4b45-a02d-3932189d1192

The open-access MAF lists 295 somatic variants for this specimen: 194 protein-altering or splice-affecting, 67 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 171, Silent 67, Intron 15, 5'UTR 13, Nonsense Mutation 9, Frame Shift Del 5, Splice Site 5, 3'UTR 3, In Frame Del 2, 3'Flank 2, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 64/332 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACO2 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 26/325 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs755024692; called by muse, mutect2
- ADAM23 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs372261190; called by mutect2, varscan2
- ADCY2 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs866989574, COSV57857225, COSV57893995; called by muse, mutect2
- ADGRV1 | c.11999C>T p.T4000M | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as rs758506587; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALDH1A1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs778276187, COSV52789879; called by muse, mutect2, varscan2
- ALG11 | c.154T>A p.L52I | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as rs746211021, COSV101584267; called by muse, mutect2, varscan2
- AMBRA1 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV54058501; called by muse, mutect2
- ANAPC2 | c.2058G>C p.K686N | Missense Mutation (SNP) | VAF 43/385 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.137); catalogued as rs375108215; called by muse, mutect2, varscan2
- ARHGEF38 | c.51G>C p.K17N | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.617); catalogued as rs762338044, COSV99486219; called by muse, mutect2, varscan2
- ASAP3 | c.1372G>A p.V458M | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1278723620, COSV60875525; called by muse, mutect2, varscan2
- BASP1 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV59470313; called by muse, mutect2, varscan2
- C1QTNF7 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.229); catalogued as rs753537535, COSV99765007; called by muse, mutect2, varscan2
- C2orf80 | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.168); catalogued as rs554082754, COSV58015225; called by muse, mutect2, varscan2
- CACHD1 | c.3704del p.P1235Lfs*7 | Frame Shift Del (DEL) | VAF 60/343 reads (17%) | catalogued as rs764948820; called by mutect2, pindel, varscan2
- CCKBR | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs201465636, COSV58101300; called by muse, mutect2, varscan2
- CCNE1 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.486); catalogued as rs757767972; called by muse, mutect2, varscan2
- CD93 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 48/462 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs1265873141, COSV55666990; called by muse, varscan2
- CDCA8 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV59237852; called by muse, mutect2, varscan2
- CELF4 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58452371; called by muse, mutect2, varscan2
- CFHR2 | c.774G>C p.Q258H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV66382016; called by muse, mutect2
- CPT2 | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 144/674 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV99598053; called by muse, mutect2, varscan2
- CREG2 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61316406, COSV61316796; called by muse, mutect2
- CYLD | c.2217C>G p.I739M | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); catalogued as COSV61092933, COSV61095795; called by muse, mutect2
- CYYR1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV54827898; called by muse, mutect2, varscan2
- DGKB | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/100 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV51783361; called by muse, mutect2, varscan2
- DHDDS | c.598C>G p.P200A | Missense Mutation (SNP) | VAF 56/444 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV99360377; called by muse, mutect2, varscan2
- DKK1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV64760149; called by muse, mutect2, varscan2
- DNAJA1 | c.390G>C p.K130N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs914592363, COSV100438595; called by muse, mutect2
- DNM1 | c.456C>G p.I152M | Missense Mutation (SNP) | VAF 77/452 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57850534; called by muse, mutect2, varscan2
- DYM | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.412); catalogued as rs1238235670; called by muse, mutect2
- EEF1AKNMT | c.1151G>A p.R384Q (on ENST00000361735 / NM_015935.5; = p.R298Q on NM_014955.3) | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751504272, COSV100675888, COSV62283334; called by muse, mutect2, varscan2
- EHD3 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as COSV59032380; called by muse, mutect2, varscan2
- ELOA2 | c.1866G>A p.M622I | Missense Mutation (SNP) | VAF 47/372 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV55296476; called by muse, mutect2, varscan2
- EVPLL | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.101); catalogued as rs1238665281; called by muse, mutect2
- FCAR | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 68/885 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.822); catalogued as COSV62029190; called by muse, mutect2
- FMN2 | c.2815G>A p.G939R | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.67); catalogued as rs1249170432, COSV60432677; called by muse, mutect2, varscan2
- GALNT9 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs781085284, COSV61097448; called by muse, mutect2, varscan2
- GBA2 | c.2227C>T p.R743W | Missense Mutation (SNP) | VAF 57/424 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs1273621765, COSV62305776; called by muse, mutect2, varscan2
- GJA9 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 52/319 reads (16%) | catalogued as COSV62532544; called by muse, mutect2, varscan2
- GTF2H4 | c.1307C>A p.S436* | Nonsense Mutation (SNP) | VAF 10/174 reads (6%) | catalogued as COSV52557614; called by muse, mutect2
- IGF2BP2 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs1050135405, COSV60483761; called by muse, mutect2, varscan2
- IGSF9B | c.3352G>A p.A1118T | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs770826046; called by muse, mutect2
- IL17RD | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV99577100; called by muse, mutect2, varscan2
- ITGA2B | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 77/521 reads (15%) | catalogued as CM021107, COSV99058163; called by muse, mutect2, varscan2
- KIAA1109 | c.11249+1G>A p.X3750_splice | Splice Site (SNP) | VAF 18/58 reads (31%) | catalogued as rs779799402; called by muse, mutect2, varscan2
- KIF21B | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 112/488 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV59760320; called by muse, mutect2, varscan2
- KMT2D | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.991); catalogued as rs548930191, COSV56442153, COSV99987300; called by muse, mutect2, varscan2
- KRT35 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs780571518, COSV55843170; called by muse, mutect2, varscan2
- LAMA1 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 73/504 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.324); catalogued as rs763042645; called by muse, mutect2, varscan2
- MAGEB6 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.64); catalogued as rs775370255, COSV66872399; called by muse, mutect2, varscan2
- MAP3K10 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 52/456 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1461889398, COSV53421449; called by muse, mutect2, varscan2
- MCM4 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 34/466 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs1242616187; called by muse, mutect2
- MGAM2 | c.4922C>T p.T1641M | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.196); catalogued as rs767574617; called by muse, mutect2
- MMP16 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54152643; called by muse, mutect2, varscan2
- MOAP1 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.9); PolyPhen benign (0.084); catalogued as COSV52092629; called by muse, mutect2
- MRTFB | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 80/808 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs528040132, COSV104402771; called by muse, mutect2
- MYL10 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs776204129; called by muse, mutect2, varscan2
- NEU2 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 103/369 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201616110; called by muse, mutect2, varscan2
- NID1 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 27/446 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as rs772635937; called by muse, mutect2
- NLRP2 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 35/920 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs371780675, COSV54757680; called by muse, mutect2
- NOA1 | c.1514G>A p.C505Y | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs758999937; called by muse, mutect2, varscan2
- NOS1 | c.3227C>T p.T1076M | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs770948047; called by muse, mutect2
- OR2F1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 50/636 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231330, COSV67331559, COSV67332142; called by muse, mutect2
- OR7D2 | c.191C>G p.S64C | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV60140976; called by mutect2, varscan2
- P2RY10 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 31/261 reads (12%) | catalogued as COSV99408978; called by muse, mutect2, varscan2
- PLXNA1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 88/861 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1243844299; called by muse, mutect2, varscan2
- POU4F1 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1023819809; called by muse, mutect2, varscan2
- PRR18 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV59454748; called by mutect2, varscan2
- RNF207 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1371682303; called by muse, mutect2, varscan2
- SELE | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV60974761; called by muse, mutect2, varscan2
- SLC12A5 | c.1210G>A p.D404N (on ENST00000454036 / NM_001134771.2; = p.D381N on NM_020708.5) | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs776238585, COSV54792870, COSV54793557; called by muse, mutect2
- SLC12A5 | c.1735G>A p.E579K (on ENST00000454036 / NM_001134771.2; = p.E556K on NM_020708.5) | Missense Mutation (SNP) | VAF 105/327 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs755740712, COSV54804463; called by muse, mutect2, varscan2
- SLC25A13 | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as CD991947; called by muse, mutect2
- SLC7A8 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765572176, COSV100382212, COSV57553011; called by muse, mutect2, varscan2
- SLCO1C1 | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200027415; called by muse, mutect2
- SORT1 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV99860780; called by muse, mutect2, varscan2
- SPINT2 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as rs1386633374, COSV56647908; called by muse, mutect2
- SRL | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 218/908 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776865624, COSV68424715; called by mutect2, varscan2
- SYNPO2 | c.1491G>C p.K497N | Missense Mutation (SNP) | VAF 44/343 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1341826720; called by muse, mutect2, varscan2
- TGFBR3 | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.366); catalogued as rs1390138351; called by muse, mutect2, varscan2
- THAP12 | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775729398; called by muse, mutect2, varscan2
- TRAF6 | c.1448G>C p.R483T | Missense Mutation (SNP) | VAF 82/520 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV61923743; called by muse, mutect2, varscan2
- TRIM5 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs768680263; called by muse, mutect2
- TTI2 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 47/414 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs962681131, COSV62452498; called by muse, mutect2, varscan2
- UBA5 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs541600523; called by muse, mutect2, varscan2
- UNC5D | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as rs938995365; called by muse, mutect2, varscan2
- ZBED9 | c.1666G>C p.E556Q | Missense Mutation (SNP) | VAF 138/636 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.051); catalogued as COSV71729194; called by muse, mutect2, varscan2
- ZFPM2 | c.2869_2871del p.E957del | In Frame Del (DEL) | VAF 54/250 reads (22%) | catalogued as rs1563575119; called by pindel, varscan2
- ACACB | c.5299G>A p.E1767K | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ACOT8 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0.013); called by muse, varscan2
- ACOT8 | c.174G>C p.Q58H | Missense Mutation (SNP) | VAF 71/301 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTBL2 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 54/750 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ADAMTS9 | c.155C>A p.S52Y | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ANKRD18A | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ARF6 | c.419G>C p.G140A | Missense Mutation (SNP) | VAF 28/315 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); called by muse, mutect2
- ARFGEF1 | c.1342C>A p.H448N | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ATM | c.1992del p.I665Lfs*2 | Frame Shift Del (DEL) | VAF 35/155 reads (23%) | called by mutect2, pindel, varscan2
- BICDL1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- BRINP3 | c.408G>C p.L136F | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CAMTA1 | c.1511A>G p.K504R | Missense Mutation (SNP) | VAF 83/578 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CD63 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 48/466 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- CFAP70 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- CHRNA5 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL2A1 | c.3949A>T p.M1317L | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); called by muse, mutect2
- CRB1 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 128/492 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- CSNK2A3 | c.353_355del p.N118del | In Frame Del (DEL) | VAF 74/676 reads (11%) | called by pindel, varscan2
- CWC27 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | called by muse, varscan2
- CXorf66 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 95/492 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DCAF11 | c.74C>G p.A25G | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.011); called by muse, mutect2
- DENND5B | c.3041G>C p.R1014T | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DHX40 | c.1777C>G p.L593V | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DIS3 | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- DNAJC13 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- DPYSL5 | c.1006A>G p.M336V | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFL1 | c.2885T>C p.I962T | Missense Mutation (SNP) | VAF 77/400 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- EIF3D | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- EP400 | c.2764G>C p.E922Q | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- EPHB1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EPSTI1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EVPLL | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.025); called by muse, mutect2
- FAM9C | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- FOXJ3 | c.1264C>G p.Q422E | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- GALNT5 | c.617A>G p.D206G | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- GFUS | c.177G>T p.E59D | Missense Mutation (SNP) | VAF 61/342 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GLOD4 | c.193G>A p.D65N (on ENST00000301328 / NM_001366247.1; = p.D50N on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/406 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GOLGA8T | c.1739T>A p.L580H | Missense Mutation (SNP) | VAF 115/576 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- GPR89A | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.283); called by muse, mutect2
- GPRASP1 | c.3103G>C p.E1035Q | Missense Mutation (SNP) | VAF 121/368 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- HELLS | c.2013A>C p.L671F | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXB2 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL12B | c.296A>G p.H99R | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITGB6 | c.142-2A>G p.X48_splice | Splice Site (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2
- JAK1 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2
- JMJD6 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KBTBD12 | c.1355_1386del p.D452Vfs*4 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | called by mutect2, pindel, varscan2
- LBH | c.130-1G>T p.X44_splice | Splice Site (SNP) | VAF 84/429 reads (20%) | called by muse, mutect2, varscan2
- LRP2 | c.5993G>A p.R1998K | Missense Mutation (SNP) | VAF 60/551 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MAPK8 | c.825C>G p.F275L | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.603); called by muse, mutect2
- MCAT | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 33/332 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- MCM6 | c.20C>A p.A7E | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MDC1 | c.5359C>T p.Q1787* | Nonsense Mutation (SNP) | VAF 26/230 reads (11%) | called by muse, mutect2, varscan2
- METTL25 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- MTURN | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MYH7B | c.5938-3C>T | Splice Region (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- NCAM1 | c.1769A>G p.N590S (on ENST00000316851 / NM_181351.5; = p.N580S on NM_000615.7) | Missense Mutation (SNP) | VAF 80/281 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NCAN | c.637G>C p.D213H | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEB | c.2416-1G>A p.X806_splice | Splice Site (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- NGEF | c.2067G>C p.K689N | Missense Mutation (SNP) | VAF 53/350 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- NOS3 | c.3319G>C p.E1107Q | Missense Mutation (SNP) | VAF 63/447 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.048); called by muse, varscan2
- NPAS4 | c.453C>G p.F151L | Missense Mutation (SNP) | VAF 211/612 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- NR2E1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 52/578 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2
- OBSCN | c.18514G>C p.A6172P | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OTX1 | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PACS2 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- PARP15 | c.40C>G p.P14A | Missense Mutation (SNP) | VAF 92/284 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PCDHGA5 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 76/642 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- PEAR1 | c.1403G>A p.C468Y | Missense Mutation (SNP) | VAF 35/347 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHF23 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PIPOX | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PKD1L1 | c.2219T>G p.L740R | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PRUNE2 | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PSMD11 | c.600C>G p.I200M | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- QSER1 | c.121G>C p.E41Q (on ENST00000399302; = p.E170Q on NM_001076786.3) | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RFX8 | c.217C>G p.H73D | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- RMDN3 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.67); called by muse, mutect2
- RPS6KA3 | c.1239G>C p.R413S | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2
- RRBP1 | c.3157G>C p.E1053Q (on ENST00000377813 / NM_001365613.2; = p.E620Q on NM_004587.3) | Missense Mutation (SNP) | VAF 39/396 reads (10%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.982); called by muse, mutect2
- RWDD1 | c.23A>C p.Q8P | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN2A | c.3343del p.E1115Kfs*3 | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | called by mutect2, pindel, varscan2
- SCPEP1 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 79/313 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SEPTIN3 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- SH3GL2 | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC25A43 | c.559A>T p.N187Y | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SMARCA1 | c.1785C>G p.D595E | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNAI2 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 38/411 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SNAPC4 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 126/596 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- SPATA31D1 | c.87C>A p.F29L | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPOCK3 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- SQLE | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- SRF | c.1200del p.T401Qfs*7 | Frame Shift Del (DEL) | VAF 27/146 reads (18%) | called by mutect2, pindel, varscan2
- SRRM2 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- STXBP2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 119/498 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SUCLA2 | c.1417C>T p.Q473* (on ENST00000643023; = p.Q452* on NM_003850.3) | Nonsense Mutation (SNP) | VAF 46/276 reads (17%) | called by muse, mutect2, varscan2
- SYMPK | c.2490+1G>C p.X830_splice | Splice Site (SNP) | VAF 37/264 reads (14%) | called by muse, mutect2, varscan2
- TDRD5 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 41/372 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TDRD9 | c.1476G>C p.Q492H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAPPC10 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- TRBV24-1 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TRIL | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UNC13B | c.4666G>A p.E1556K | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- ZNF165 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZNF71 | c.1405G>A p.G469S | Missense Mutation (SNP) | VAF 46/597 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- ABCA3 | c.2661C>T p.L887= | Silent (SNP) | VAF 110/658 reads (17%) | catalogued as rs1165693335; called by mutect2, varscan2
- ABCA7 | c.6111C>T p.F2037= | Silent (SNP) | VAF 19/265 reads (7%) | called by muse, mutect2
- ADRA1B | c.165C>T p.F55= | Silent (SNP) | VAF 51/485 reads (11%) | called by muse, mutect2, varscan2
- AFM | c.330C>T p.F110= | Silent (SNP) | VAF 27/542 reads (5%) | called by muse, mutect2
- BMPR1B | c.1215C>T p.L405= | Silent (SNP) | VAF 28/374 reads (7%) | called by muse, mutect2
- BPNT1 | c.60A>G p.Q20= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as rs941227996; called by muse, mutect2, varscan2
- BTN2A2 | c.489G>A p.G163= | Silent (SNP) | VAF 28/241 reads (12%) | called by muse, mutect2, varscan2
- CIC | c.3522G>A p.P1174= | Silent (SNP) | VAF 81/533 reads (15%) | catalogued as rs766523175, COSV50546873; called by muse, mutect2, varscan2
- CSTF2T | c.1302G>A p.E434= | Silent (SNP) | VAF 135/618 reads (22%) | called by mutect2, varscan2
- DSP | c.4566G>A p.T1522= | Silent (SNP) | VAF 21/761 reads (3%) | catalogued as rs1159243386, COSV101131739; called by muse, mutect2
- FHDC1 | c.3012C>T p.R1004= | Silent (SNP) | VAF 40/273 reads (15%) | catalogued as rs1378204756, COSV52603074; called by muse, mutect2, varscan2
- FRY | c.3357G>A p.L1119= | Silent (SNP) | VAF 41/222 reads (18%) | called by muse, mutect2, varscan2
- GIGYF2 | c.3717C>G p.L1239= | Silent (SNP) | VAF 69/555 reads (12%) | called by muse, mutect2, varscan2
- GRIN2A | c.2520C>G p.L840= | Silent (SNP) | VAF 152/715 reads (21%) | catalogued as COSV58055399; called by muse, mutect2, varscan2
- HHAT | c.972C>T p.C324= | Silent (SNP) | VAF 43/372 reads (12%) | catalogued as rs201949677, COSV54793455; called by muse, mutect2, varscan2
- HMG20B | c.450C>T p.I150= | Silent (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2
- HOXB8 | c.513G>A p.L171= | Silent (SNP) | VAF 30/430 reads (7%) | called by muse, mutect2
- IFNA5 | c.219G>A p.K73= | Silent (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2, varscan2
- IPO5 | c.1629G>A p.E543= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs769103564; called by muse, mutect2
- ITGAE | c.1935C>T p.F645= | Silent (SNP) | VAF 26/346 reads (8%) | catalogued as rs371911996; called by muse, mutect2
- KRT5 | c.492G>A p.V164= | Silent (SNP) | VAF 19/245 reads (8%) | catalogued as rs775166393; called by muse, mutect2
- KRT6B | c.435G>C p.L145= | Silent (SNP) | VAF 112/1634 reads (7%) | called by muse, mutect2
- KRT79 | c.66C>T p.S22= | Silent (SNP) | VAF 96/444 reads (22%) | catalogued as rs142260878; called by muse, mutect2, varscan2
- LCT | c.5073C>T p.L1691= | Silent (SNP) | VAF 75/503 reads (15%) | called by muse, mutect2, varscan2
- LGI2 | c.111C>G p.P37= | Silent (SNP) | VAF 36/209 reads (17%) | catalogued as COSV66123337; called by muse, mutect2, varscan2
- LILRB4 | c.348G>A p.V116= | Silent (SNP) | VAF 30/360 reads (8%) | called by muse, mutect2
- LRP12 | c.429G>A p.S143= | Silent (SNP) | VAF 9/134 reads (7%) | catalogued as rs1157918883, COSV52633245, COSV52633847; called by muse, mutect2
- MAP3K21 | c.552C>T p.I184= | Silent (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- MICAL3 | c.2697C>T p.S899= | Silent (SNP) | VAF 130/632 reads (21%) | catalogued as COSV52896425; called by mutect2, varscan2
- MKNK1 | c.849G>A p.L283= | Silent (SNP) | VAF 23/145 reads (16%) | called by muse, mutect2, varscan2
- MKNK1 | c.573G>A p.G191= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- MROH7 | c.870G>T p.V290= | Silent (SNP) | VAF 62/532 reads (12%) | called by muse, mutect2, varscan2
- NAA11 | c.147C>T p.D49= | Silent (SNP) | VAF 32/604 reads (5%) | catalogued as COSV54516092; called by muse, mutect2
- NEB | c.4092G>T p.L1364= | Silent (SNP) | VAF 24/220 reads (11%) | catalogued as COSV51467684; called by muse, mutect2, varscan2
- NEURL4 | c.3324C>T p.G1108= | Silent (SNP) | VAF 36/247 reads (15%) | catalogued as rs1402091959; called by muse, mutect2, varscan2
- OTOG | c.8256C>T p.L2752= | Silent (SNP) | VAF 16/228 reads (7%) | catalogued as rs749120808, COSV61131421; ClinVar: likely benign; called by muse, mutect2
- PCDHA2 | c.2316C>T p.F772= | Silent (SNP) | VAF 36/277 reads (13%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1929G>A p.P643= | Silent (SNP) | VAF 107/759 reads (14%) | catalogued as COSV65347321; called by muse, mutect2, varscan2
- PCDHA7 | c.2149C>T p.L717= | Silent (SNP) | VAF 68/465 reads (15%) | catalogued as COSV65335262; called by muse, mutect2, varscan2
- PCDHGA4 | c.636C>T p.D212= | Silent (SNP) | VAF 55/502 reads (11%) | catalogued as rs750434737, COSV53977600; called by muse, mutect2, varscan2
- PHF20L1 | c.1401G>A p.E467= | Silent (SNP) | VAF 20/248 reads (8%) | catalogued as COSV55198847; called by muse, mutect2
- PIP5K1C | c.642G>T p.R214= | Silent (SNP) | VAF 59/199 reads (30%) | called by muse, mutect2, varscan2
- PLCG1 | c.2646G>A p.Q882= | Silent (SNP) | VAF 27/160 reads (17%) | called by muse, mutect2, varscan2
- PTGIR | c.261C>T p.G87= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as rs200330439; called by muse, mutect2, varscan2
- RAB40B | c.777C>T p.L259= | Silent (SNP) | VAF 128/524 reads (24%) | catalogued as rs1275860745; called by muse, mutect2, varscan2
- REV3L | c.1356A>G p.E452= | Silent (SNP) | VAF 27/267 reads (10%) | called by muse, mutect2
- RPS6KA2 | c.1665C>T p.F555= | Silent (SNP) | VAF 50/259 reads (19%) | catalogued as rs202226024; called by muse, mutect2, varscan2
- RTL5 | c.571C>T p.L191= | Silent (SNP) | VAF 104/336 reads (31%) | called by muse, mutect2, varscan2
- RUBCN | c.558C>T p.I186= | Silent (SNP) | VAF 34/288 reads (12%) | catalogued as rs774034505, COSV56365453; called by muse, mutect2, varscan2
- RYR2 | c.2127G>C p.G709= | Silent (SNP) | VAF 22/174 reads (13%) | catalogued as COSV100773212; called by muse, mutect2, varscan2
- SEMA3B | c.1344C>T p.L448= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs1279372304; called by muse, mutect2, varscan2
- SLC12A5 | c.1611G>A p.S537= (on ENST00000454036 / NM_001134771.2; = p.S514= on NM_020708.5) | Silent (SNP) | VAF 109/326 reads (33%) | catalogued as rs771067022, COSV54793967; called by muse, varscan2
- SLC22A31 | c.798C>T p.F266= | Silent (SNP) | VAF 22/262 reads (8%) | called by muse, mutect2
- SLC7A9 | c.216C>T p.C72= | Silent (SNP) | VAF 88/885 reads (10%) | catalogued as rs756984428, COSV50082801; called by muse, mutect2, varscan2
- SPATC1L | c.834C>T p.L278= (on ENST00000291672 / NM_001142854.2; = p.L124= on NM_032261.5) | Silent (SNP) | VAF 49/340 reads (14%) | called by muse, mutect2, varscan2
- SYNM | c.2122T>C p.L708= | Silent (SNP) | VAF 30/768 reads (4%) | called by muse, mutect2
- TBC1D22B | c.720G>A p.R240= | Silent (SNP) | VAF 22/228 reads (10%) | catalogued as rs1175528113, COSV65143064; called by muse, mutect2, varscan2
- TENM4 | c.1842C>T p.C614= | Silent (SNP) | VAF 57/373 reads (15%) | catalogued as COSV53634290; called by muse, mutect2, varscan2
- TLX2 | c.780C>T p.F260= | Silent (SNP) | VAF 32/129 reads (25%) | called by muse, mutect2, varscan2
- TRAV8-7 | c.120C>T p.C40= | Silent (SNP) | VAF 110/282 reads (39%) | called by muse, mutect2, varscan2
- TRPM2 | c.2868C>T p.L956= | Silent (SNP) | VAF 73/237 reads (31%) | catalogued as rs142589153; called by muse, mutect2, varscan2
- TTC37 | c.2748C>T p.L916= | Silent (SNP) | VAF 30/199 reads (15%) | catalogued as COSV62454414; called by mutect2, varscan2
- USP54 | c.297C>T p.L99= | Silent (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- WASF3 | c.1218C>T p.G406= | Silent (SNP) | VAF 29/228 reads (13%) | called by muse, mutect2, varscan2
- ZFYVE27 | c.480G>C p.L160= | Silent (SNP) | VAF 74/797 reads (9%) | called by muse, mutect2
- ZNF292 | c.426G>A p.E142= | Silent (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- ZNF71 | c.1005C>T p.F335= | Silent (SNP) | VAF 50/874 reads (6%) | called by muse, mutect2
- ARL14EPL | c.-1G>A | 5'UTR (SNP) | VAF 13/111 reads (12%) | catalogued as rs1391726563; called by muse, mutect2, varscan2
- ATP6V0C | c.-36C>T | 5'UTR (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- BCAS3 | c.662-2625C>T | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as rs989319859; called by muse, mutect2
- BRD8 | c.117-699C>T | Intron (SNP) | VAF 7/30 reads (23%) | catalogued as rs1353712221; called by muse, mutect2, varscan2
- C19orf12 | chr19:29700116 G>A | 3'Flank (SNP) | VAF 50/393 reads (13%) | called by muse, mutect2, varscan2
- CAPRIN1 | c.1-37C>T | Intron (SNP) | VAF 11/55 reads (20%) | catalogued as rs548459001; called by muse, mutect2, varscan2
- CASC3 | chr17:40140512 del CGTAAGTACCTCGCCGGTGGTGGCCGTTCTC | 5'UTR (DEL) | VAF 75/409 reads (18%) | called by mutect2, pindel, varscan2
- CHORDC1 | c.493-492C>T | Intron (SNP) | VAF 22/96 reads (23%) | catalogued as rs1425996038; called by muse, mutect2, varscan2
- COL4A3 | c.-17C>G | 5'UTR (SNP) | VAF 15/138 reads (11%) | called by muse, mutect2, varscan2
- EFHC1 | c.723+477G>C | Intron (SNP) | VAF 46/422 reads (11%) | called by muse, mutect2, varscan2
- EHHADH | c.178+12C>T | Intron (SNP) | VAF 29/232 reads (13%) | called by muse, mutect2, varscan2
- IVL | c.-1G>C | 5'UTR (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- MED15 | c.68+11180C>T | Intron (SNP) | VAF 23/165 reads (14%) | catalogued as rs901665696; called by muse, varscan2
- MEIS1 | c.1024+61C>G | Intron (SNP) | VAF 28/336 reads (8%) | called by muse, mutect2
- MXD3 | c.-7C>T | 5'UTR (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- PCDHGA3 | c.2425-67983G>C | Intron (SNP) | VAF 26/273 reads (10%) | called by muse, mutect2
- PMS2P3 | n.334G>A | RNA (SNP) | VAF 6/53 reads (11%) | catalogued as rs1348559627; called by muse, mutect2
- POLH | c.*5664A>T | 3'UTR (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- POLR1C | c.*15G>A | 3'UTR (SNP) | VAF 58/678 reads (9%) | called by muse, mutect2
- RBPJ | c.-155G>C | 5'UTR (SNP) | VAF 41/219 reads (19%) | called by muse, mutect2, varscan2
- RGSL1 | c.*29C>G | 3'UTR (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- RMDN2 | c.452+20800G>T | Intron (SNP) | VAF 31/293 reads (11%) | called by muse, mutect2, varscan2
- RNU7-115P | chr17:64821783 C>G | 3'Flank (SNP) | VAF 58/708 reads (8%) | called by muse, mutect2
- RP9 | c.183+18A>T | Intron (SNP) | VAF 42/232 reads (18%) | called by mutect2, varscan2
- RPS28 | c.40-22G>C | Intron (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2, varscan2
- SAMM50 | c.-47C>G | 5'UTR (SNP) | VAF 31/281 reads (11%) | called by muse, mutect2, varscan2
- SERPING1 | c.685+43G>C | Intron (SNP) | VAF 80/358 reads (22%) | called by muse, mutect2, varscan2
- SLC38A1 | c.-525G>A | 5'UTR (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- SNX21 | c.448-183C>T | Intron (SNP) | VAF 40/384 reads (10%) | called by muse, varscan2
- SSH3 | c.-51G>A | 5'UTR (SNP) | VAF 14/155 reads (9%) | called by muse, mutect2
- TBC1D12 | c.-3C>T | 5'UTR (SNP) | VAF 48/296 reads (16%) | catalogued as rs776687705, COSV56552223; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 101/295 reads (34%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- UCHL1 | c.45+48G>C | Intron (SNP) | VAF 27/217 reads (12%) | called by muse, mutect2, varscan2
- ZNF134 | c.-250G>A | 5'UTR (SNP) | VAF 31/151 reads (21%) | called by muse, mutect2, varscan2
